Somatic mutation profile of tumor specimen TCGA-06-0650-01A (aliquot TCGA-06-0650-01A-02D-1696-08) from TCGA case TCGA-06-0650, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.9 years (14,560 days).
Specimen TCGA-06-0650-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d582bfee-abb6-400c-94ee-1a50b23879b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0650-10A (Blood Derived Normal), aliquot TCGA-06-0650-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76aba3c0-a81a-4f85-abe9-e02484fdf857

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABLIM3 | c.1992G>C p.E664D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV58641713; called by muse, mutect2, varscan2
- APC2 | c.2089C>T p.H697Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV52017124; called by muse, mutect2, varscan2
- ASCC3 | c.5431G>A p.E1811K | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as COSV100976841, COSV64973769; called by muse, mutect2, varscan2
- CD209 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs751060553, COSV52651524; called by muse, varscan2
- CEP41 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 43/451 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs782590600, COSV56219077; called by muse, mutect2
- FCGBP | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs142198641; called by muse, mutect2, varscan2
- FMR1NB | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV65071464, COSV65073365; called by muse, mutect2
- FRAS1 | c.7733C>T p.T2578I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.152); catalogued as COSV53600148; called by muse, mutect2, varscan2
- GABRB3 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as rs1453012489, COSV54657264, COSV54676874; called by muse, mutect2
- GPR143 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852297, CM981400, COSV66632168; called by muse, mutect2, varscan2
- INTS4 | c.1738C>G p.L580V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV71087654; called by muse, mutect2, varscan2
- KCNB2 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV73049570; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV65442685; called by muse, mutect2
- MUC17 | c.4220C>T p.P1407L | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs759205801, COSV60284198; called by muse, varscan2
- MUC2 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); catalogued as rs781049326, COSV61238863; called by muse, mutect2, varscan2
- MYH2 | c.4124C>G p.A1375G | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV55434785; called by muse, mutect2, varscan2
- NLRP5 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537471101, COSV66762321; called by muse, mutect2
- NPTX1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs1447587351, COSV60774615; called by muse, mutect2
- PARP4 | c.4220G>A p.S1407N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV67961184; called by muse, mutect2, varscan2
- PNLDC1 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs138386704; called by muse, mutect2, varscan2
- QKI | c.542C>G p.P181R | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV51691582, COSV99276255; called by muse, mutect2, varscan2
- RBM47 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.293); catalogued as COSV55932552; called by muse, mutect2
- SPDYC | c.298C>A p.H100N | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65865029; called by muse, mutect2
- SRPK3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs781909701, COSV54206843; called by muse, mutect2, varscan2
- TBX18 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.365); catalogued as rs747562979, COSV63736506; called by muse, mutect2, varscan2
- TRABD2A | c.1287G>T p.R429S (on ENST00000409520 / NM_001277053.2; = p.R380S on NM_001080824.3) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52854755; called by muse, mutect2, varscan2
- TSHZ2 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs141985599; called by muse, mutect2, varscan2
- CASR | c.279G>A p.L93= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as COSV56135916; called by muse, mutect2, varscan2
- CSN1S1 | c.495C>T p.S165= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs1168866381, COSV55890159; called by muse, mutect2, varscan2
- GRIPAP1 | c.546C>T p.T182= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV64551447; called by muse, mutect2, varscan2
- INTS11 | c.744C>G p.L248= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV60087843; called by muse, mutect2, varscan2
- PTPRD | c.2907G>A p.E969= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV61936687; called by muse, mutect2, varscan2
- PTPRJ | c.816G>A p.P272= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs770215254, COSV69249818; called by muse, mutect2
- RP1L1 | c.5520T>A p.A1840= | Silent (SNP) | VAF 38/298 reads (13%) | catalogued as rs752858983, COSV66753430; called by muse, mutect2, varscan2
- THEM5 | c.501C>T p.D167= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs372391484; called by muse, mutect2, varscan2
- WDR13 | c.1278G>A p.T426= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs144018865, COSV54331330; called by muse, mutect2, varscan2
- EPHA8 | c.1315+18G>A | Intron (SNP) | VAF 12/81 reads (15%) | catalogued as rs199679973, COSV51273871; called by muse, mutect2, varscan2
